Somatic mutation profile of tumor specimen ALCH-B28C-TTP1-A (aliquot ALCH-B28C-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B28C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.1 years (23,415 days).
Specimen ALCH-B28C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98714c92-b250-4f82-9c3a-2617bcdbfe72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B28C-NB1-A (Blood Derived Normal), aliquot ALCH-B28C-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd755197-264c-4542-8cf8-1f1e207d0747

The open-access MAF lists 48 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Intron 8, Silent 7, 3'UTR 3, Frame Shift Del 2, Translation Start Site 1, 3'Flank 1, Nonsense Mutation 1, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCNT4 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV100466488; called by muse, mutect2
- IGHV4-28 | c.46+1G>A p.X16_splice | Splice Site (SNP) | VAF 17/352 reads (5%) | catalogued as rs782487364; called by muse, mutect2
- INPP5J | c.2713G>A p.E905K (on ENST00000331075 / NM_001284285.2; = p.E537K on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as rs1025721753; called by muse, mutect2, varscan2
- ITGB2 | c.1952C>T p.S651F (on ENST00000302347; = p.S627F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV56609062; called by muse, mutect2
- MAG | c.458C>A p.T153K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV62702449; called by muse, mutect2
- MYH14 | c.4823G>A p.R1608Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs368076336; called by muse, mutect2, varscan2
- NALCN | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1307862342; called by mutect2, varscan2
- PRDM9 | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57010376, COSV57010765; called by muse, mutect2
- PYGM | c.2277C>G p.F759L | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV51224012; called by muse, mutect2
- SH3BP5 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1305246485; called by muse, mutect2
- SORBS1 | c.571A>G p.T191A (on ENST00000361941 / NM_001034954.2; = p.T159A on NM_015385.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1261732785; called by muse, mutect2, varscan2
- TINAG | c.641C>G p.T214R | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1359782980; called by muse, mutect2
- ABCC8 | c.4120-8C>T | Splice Region (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- AKAP12 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATF2 | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CIC | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CLTC | c.2372T>C p.L791S | Missense Mutation (SNP) | VAF 6/196 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KMT2E | c.4732C>G p.Q1578E | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2
- LRRC3B | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- MUC22 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.07); called by muse, mutect2
- NBPF9 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 14/465 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- ORC2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 11/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- QSOX1 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- SGSM1 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SLC26A6 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX2 | c.540_550del p.K181Qfs*39 | Frame Shift Del (DEL) | VAF 14/156 reads (9%) | called by mutect2, pindel
- UBQLN1 | c.1725_1729del p.D575Efs*5 | Frame Shift Del (DEL) | VAF 15/145 reads (10%) | called by mutect2, pindel
- WDFY3 | c.9475C>A p.L3159M | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.205); called by muse, mutect2
- ABCB4 | c.2667G>A p.L889= | Silent (SNP) | VAF 9/293 reads (3%) | called by muse, mutect2
- ACTN2 | c.1995C>T p.I665= | Silent (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- AURKC | c.213G>A p.L71= (on ENST00000302804 / NM_001015878.2; = p.L37= on NM_003160.3) | Silent (SNP) | VAF 10/302 reads (3%) | called by muse, mutect2
- B3GALT4 | c.909C>T p.L303= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs930204927, COSV101005564; called by muse, mutect2
- NDST1 | c.2595G>A p.K865= | Silent (SNP) | VAF 9/222 reads (4%) | called by muse, mutect2
- PRPF6 | c.2502G>A p.L834= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SLC4A1 | c.1278C>T p.L426= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- C12orf76 | n.612G>A | RNA (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- CACNG7 | c.570+39G>C | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99711900; called by muse, mutect2
- CENPL | c.420+776C>A | Intron (SNP) | VAF 15/205 reads (7%) | catalogued as COSV61892791, COSV61893124; called by muse, mutect2
- EIF4E2 | chr2:232574071 G>A | 3'Flank (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- FOXP2 | c.*783T>C | 3'UTR (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- H3-2 | c.*258C>G | 3'UTR (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- KHDRBS3 | c.88+942C>G | Intron (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- PPP2R2B | c.70+21469G>A | Intron (SNP) | VAF 8/238 reads (3%) | called by muse, mutect2
- SRP19 | c.*384G>C | 3'UTR (SNP) | VAF 10/315 reads (3%) | called by muse, mutect2
- STX17 | c.190-5295G>A | Intron (SNP) | VAF 6/92 reads (7%) | catalogued as rs1180571914; called by muse, mutect2
- TEX35 | c.543+50C>T | Intron (SNP) | VAF 12/49 reads (24%) | catalogued as rs1256953434; called by muse, mutect2, varscan2
- TMEM164 | c.391-11987G>T | Intron (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- TSPAN31 | c.313-163G>A | Intron (SNP) | VAF 46/273 reads (17%) | catalogued as rs776316263, COSV57276075; called by muse, mutect2, varscan2
